Gene-level copy-number profile of tumor specimen TCGA-61-1914-01A from TCGA case TCGA-61-1914, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.3 years (23,850 days).
Specimen TCGA-61-1914-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.841485f0-4b77-4204-b84a-315f8c1fb560.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1914-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24f333e9-0aee-455d-b21d-3292c082f198

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 330; copy number 2: 11,989; copy number 3: 11,471; copy number 4: 22,421; copy number 5: 7,508; copy number 6: 3,391; copy number 7: 451; copy number 8: 1,433; copy number 9: 295; copy number 10: 19; copy number 11: 507.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1914-01A-01D-0577-01): tumor purity 0.76, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:68,004,247–68,545,621, 4 genes (within-gene range 0–3): TAFA1, COPS8P2, AC107626.1, AC104167.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 821 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:175,767,558–177,349,166, 19 genes, copy number 10: RNU6-1317P, NAALADL2-AS1, AC104640.1, ACTG1P23, EI24P1, AC104640.2, AC117434.1, LINC01208, MIR7977, RNA5SP147, LINC01209, MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1.
- chr5:58,198–16,941,951, 295 genes, copy number 9 (broad region; genes not listed).
- chr8:115,408,496–145,066,685, 507 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
